Somatic mutation profile of tumor specimen 0DN9ER from CCDI case PBCBLV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.5 years (2,358 days).
Specimen 0DN9ER: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7a1ac025-235c-43af-92d2-e01c8cd30425.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DN9EZ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ac58428a-5941-4348-af93-a83939038699

The open-access MAF lists 13 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Nonsense Mutation 3, 3'UTR 2, 5'Flank 1, 3'Flank 1, Frame Shift Del 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRL2 | c.148C>T p.R50* | Nonsense Mutation (SNP) | VAF 38/639 reads (6%) | catalogued as COSV54650641; called by muse, mutect2
- MMP23B | c.1153C>T p.R385* | Nonsense Mutation (SNP) | VAF 40/321 reads (12%) | catalogued as rs1160884679, COSV100477252; called by muse, mutect2, varscan2
- PUF60 | c.1285G>T p.E429* (on ENST00000526683 / NM_001362896.2; = p.E412* on NM_014281.5 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 102/447 reads (23%) | catalogued as COSV57595635; called by muse, mutect2, varscan2
- CATSPERB | c.3157C>A p.P1053T | Missense Mutation (SNP) | VAF 28/461 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); called by muse, mutect2
- CNPY3 | c.180G>C p.K60N | Missense Mutation (SNP) | VAF 30/749 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- KIFBP | c.447G>C p.W149C | Missense Mutation (SNP) | VAF 62/844 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- RAB32 | c.452G>A p.S151N | Missense Mutation (SNP) | VAF 230/536 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ZNF778 | c.2131_2143del p.K711Afs*43 | Frame Shift Del (DEL) | VAF 78/385 reads (20%) | called by mutect2, pindel, varscan2
- FOXA3 | c.828C>T p.P276= | Silent (SNP) | VAF 34/233 reads (15%) | catalogued as rs772799849; called by muse, mutect2, varscan2
- HMGB1 | c.*85T>C | 3'UTR (SNP) | VAF 11/170 reads (6%) | catalogued as COSV100360835; called by muse, mutect2
- SLC52A2 | chr8:144358539 del C | 5'Flank (DEL) | VAF 3/20 reads (15%) | called by pindel, varscan2
- TAGLN | chr11:117206441 T>A | 3'Flank (SNP) | VAF 67/170 reads (39%) | called by muse, mutect2, varscan2
- UNK | c.*34_*36del | 3'UTR (DEL) | VAF 91/284 reads (32%) | called by pindel, varscan2
